Somatic mutation profile of tumor specimen TCGA-QB-AA9O-06A (aliquot TCGA-QB-AA9O-06A-11D-A397-08) from TCGA case TCGA-QB-AA9O, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.9 years (27,009 days).
Specimen TCGA-QB-AA9O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b67dbca7-6dd2-4f06-bb8c-ad01729a12d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QB-AA9O-10A (Blood Derived Normal), aliquot TCGA-QB-AA9O-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0f34f2b-a414-4a67-b0d8-6cf6b853b43e

The open-access MAF lists 1,830 somatic variants for this specimen: 1,183 protein-altering or splice-affecting, 594 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,075, Silent 594, Nonsense Mutation 74, Intron 19, RNA 19, Splice Site 14, Splice Region 12, 3'UTR 8, Frame Shift Del 6, 5'Flank 3, 5'UTR 2, Frame Shift Ins 2.

Variants (750 of 1,830; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs121908228, CM023611, COSV64211919; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CRLF2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1319865856, COSV67493811; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAI2 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as rs1060502202, COSV100210084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- G6PC | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs104894569, CM960671, CM990610, COSV99520982; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HBB | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs33965000, CM066871, CM850041, CX973665, COSV100092942; ClinVar: other / pathogenic; called by muse, mutect2, varscan2
- MAP2K2 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 39/77 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs121434498, CM080435, CM086853, COSV53562382, COSV53564387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 52/109 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 74/145 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs199473153, CM033020, COSV61125197; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62791251; called by muse, mutect2, varscan2
- ABCA5 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.127); catalogued as rs1025689034, COSV101201285; called by muse, mutect2, varscan2
- ABCB5 | c.1570C>T p.Q524* (on ENST00000404938 / NM_001163941.2; = p.Q79* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV51709036; called by muse, mutect2, varscan2
- ABCB5 | c.2621G>A p.G874E (on ENST00000404938 / NM_001163941.2; = p.G429E on NM_178559.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165165839, COSV99329723; called by muse, mutect2, varscan2
- ABCC4 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs1280856591, COSV100972813; called by muse, mutect2, varscan2
- ABCC6 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1453926113, COSV52746550; called by muse, mutect2, varscan2
- ABCC6 | c.1041G>A p.W347* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99229667; called by muse, mutect2, varscan2
- ABCC9 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99687293; called by muse, mutect2, varscan2
- ABCC9 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99687296; called by muse, mutect2, varscan2
- ABI3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56801384; called by muse, mutect2, varscan2
- ABI3BP | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as rs1429896960, COSV99428629; called by muse, mutect2, varscan2
- ABL2 | c.3382C>T p.P1128S (on ENST00000502732 / NM_007314.4; = p.P1113S on NM_005158.5) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.574); catalogued as COSV61011361; called by muse, mutect2, varscan2
- ACAN | c.4354C>T p.P1452S | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1199278824, COSV100719335; called by muse, varscan2
- ACP4 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV54516738, COSV54516942; called by muse, mutect2, varscan2
- ACP7 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs756821395, COSV100488619; called by muse, mutect2, varscan2
- ACSM4 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV68067328; called by muse, mutect2, varscan2
- ACTB | c.1030T>C p.S344P | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100079961, COSV59318847; called by muse, mutect2, varscan2
- ACTN3 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as rs771328993, COSV101557890; called by muse, mutect2, varscan2
- ACTR8 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99213896; called by muse, mutect2, varscan2
- ADAM18 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs865870698, COSV55844130; called by muse, mutect2, varscan2
- ADAM21 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.02); catalogued as rs762521545, COSV50809100; called by muse, mutect2, varscan2
- ADAM23 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100008871; called by muse, mutect2, varscan2
- ADAM32 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs957652162, COSV65950171; called by muse, mutect2, varscan2
- ADAM7 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as rs771552255, COSV51542690; called by muse, mutect2, varscan2
- ADAM7 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.672); catalogued as COSV99445097; called by muse, mutect2, varscan2
- ADAMDEC1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.498); catalogued as COSV56478081; called by muse, mutect2, varscan2
- ADAMTS10 | c.3253C>T p.Q1085* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV54352331; called by muse, mutect2, varscan2
- ADAMTS19 | c.2161G>C p.A721P | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.972); catalogued as COSV99181815; called by muse, mutect2, varscan2
- ADAMTS20 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1270702920, COSV67129732; called by muse, mutect2, varscan2
- ADAMTS9 | c.3376G>A p.G1126R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900251; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100416960; called by muse, mutect2, varscan2
- ADGRA1 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV101192748; called by muse, mutect2, varscan2
- ADGRA2 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178433; called by muse, mutect2, varscan2
- ADGRB3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs766735540, COSV65381042; called by muse, mutect2, varscan2
- ADGRG4 | c.9239C>T p.P3080L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as COSV54964133, COSV99796853; called by muse, mutect2, varscan2
- ADGRL2 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591657; called by muse, mutect2, varscan2
- ADGRL2 | c.4322G>A p.G1441E (on ENST00000370717 / NM_001366005.1; = p.G1385E on NM_012302.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as COSV99591658; called by muse, mutect2
- ADGRL4 | c.1969G>A p.G657R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465967128, COSV100876569; called by muse, mutect2, varscan2
- ADGRV1 | c.3712C>T p.P1238S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450507647, COSV67995730; called by muse, mutect2, varscan2
- ADGRV1 | c.4248G>A p.M1416I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV67984405, COSV67989470; called by muse, mutect2, varscan2
- ADGRV1 | c.7078C>T p.R2360C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs369782677; called by muse, mutect2, varscan2
- ADGRV1 | c.9752G>A p.G3251E | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV101316535; called by muse, mutect2, varscan2
- ADGRV1 | c.11128T>G p.F3710V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV101316536; called by muse, mutect2, varscan2
- AFF1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 31/54 reads (57%) | catalogued as rs753451653, COSV100321078; called by muse, mutect2, varscan2
- AGR2 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs778625347, COSV101290831; called by muse, mutect2, varscan2
- AHDC1 | c.4781C>T p.P1594L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1309904393, COSV99899760; called by muse, mutect2, varscan2
- AK5 | c.859A>G p.K287E (on ENST00000354567 / NM_174858.3; = p.K261E on NM_012093.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV100643409; called by muse, mutect2, varscan2
- AKAP7 | c.1012C>T p.Q338* (on ENST00000431975 / NM_016377.4; = p.Q71* on NM_004842.4) | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99541807; called by muse, mutect2, varscan2
- ALKAL1 | c.236A>C p.H79P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100660285; called by muse, mutect2, varscan2
- ALOX12B | c.1533-1G>A p.X511_splice | Splice Site (SNP) | VAF 32/171 reads (19%) | catalogued as COSV100047753; called by muse, mutect2, varscan2
- ALPK2 | c.6212A>T p.K2071I | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100864822; called by muse, mutect2, varscan2
- ALPK2 | c.5054G>A p.R1685K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV100864823; called by muse, mutect2, varscan2
- AMER3 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs577463247, COSV58466798; called by muse, mutect2, varscan2
- AMY2A | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70214317; called by mutect2, varscan2
- ANGPT1 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52454280, COSV99863124; called by muse, mutect2
- ANK1 | c.2201G>A p.G734E | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99226900; called by muse, mutect2, varscan2
- ANK3 | c.10457C>T p.S3486L | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV99782437; called by muse, mutect2, varscan2
- ANK3 | c.5474A>C p.Y1825S | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99782440; called by muse, mutect2, varscan2
- ANK3 | c.4268G>A p.G1423E (on ENST00000280772 / NM_001320874.2; = p.G557E on NM_001149.3) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99782441; called by muse, mutect2, varscan2
- ANK3 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.257); catalogued as COSV55054155, COSV55076599; called by muse, mutect2, varscan2
- ANKEF1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs755107512, COSV65691976; called by muse, mutect2, varscan2
- ANKFN1 | c.1450C>T p.L484= | Splice Region (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100594236; called by muse, mutect2, varscan2
- ANKFN1 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as rs761817258, COSV59462402; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7307C>T p.S2436F | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as rs774909171, COSV99784512; called by muse, mutect2, varscan2
- ANKRD42 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.883); catalogued as COSV99474196; called by muse, mutect2, varscan2
- ANO4 | c.1979G>T p.W660L (on ENST00000392977 / NM_001286615.2; = p.W625L on NM_178826.4) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100153871; called by muse, mutect2, varscan2
- ANO5 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100202246; called by muse, mutect2, varscan2
- AP1B1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100434838; called by muse, mutect2, varscan2
- APOB | c.8224C>T p.Q2742* | Nonsense Mutation (SNP) | VAF 47/183 reads (26%) | catalogued as COSV99268186; called by muse, mutect2, varscan2
- APOB | c.3220G>A p.G1074R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72653074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARG1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99256283; called by muse, mutect2, varscan2
- ARHGAP27 | c.1658C>T p.S553F (on ENST00000428638 / NM_001282290.1; = p.S212F on NM_199282.3) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs267604916, COSV65357860; called by muse, mutect2, varscan2
- ARHGEF2 | c.2558C>T p.A853V (on ENST00000361247 / NM_001162383.2; = p.A825V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs1318066744, COSV100561184, COSV58109001; called by muse, mutect2, varscan2
- ARHGEF5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV99282861, COSV99283215; called by muse, mutect2, varscan2
- ARHGEF5 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs547089301, COSV99283220; called by muse, mutect2, varscan2
- ARMC7 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1248003701, COSV99822748; called by muse, mutect2, varscan2
- ARMC7 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs1427354266, COSV99822751; called by muse, mutect2, varscan2
- ARRB2 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99347290; called by muse, mutect2, varscan2
- ARRDC5 | c.179G>A p.G60E (on ENST00000381781; = p.G46E on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101108267; called by muse, mutect2, varscan2
- ART3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs778360156, COSV100587978; called by muse, mutect2, varscan2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ATF2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99909028; called by muse, mutect2, varscan2
- ATF2 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1254782070, COSV99909030; called by muse, varscan2
- ATF6 | c.1481G>T p.R494M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1401507122, COSV100909505; called by muse, mutect2, varscan2
- ATP11B | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100018138; called by muse, mutect2, varscan2
- ATP13A1 | c.2337C>T p.G779= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as rs1360702833, COSV99366622; called by muse, mutect2, varscan2
- ATP2A2 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100428913; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs757432786, COSV100376896, COSV100377176; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1400208410, COSV100377178; called by muse, mutect2, varscan2
- ATP8B4 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs1201109425, COSV99467575; called by muse, mutect2, varscan2
- AXIN2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100196970, COSV61057637, COSV61059994; called by muse, mutect2, varscan2
- B4GALNT3 | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99843624; called by muse, mutect2, varscan2
- BARD1 | c.354T>G p.N118K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV99639905; called by muse, mutect2, varscan2
- BARHL2 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178542684, COSV64981248; called by muse, mutect2, varscan2
- BCAS2 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1462787778, COSV101058666; called by muse, mutect2
- BCL11B | c.241T>G p.C81G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100595937; called by muse, mutect2, varscan2
- BCL2L11 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs1250218441, COSV100427519; called by muse, mutect2, varscan2
- BCL6B | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs751964952, COSV99546933; called by muse, mutect2, varscan2
- BEST2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs1452026355, COSV99244678; called by muse, mutect2, varscan2
- BFSP1 | c.1907T>C p.I636T | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100925464; called by muse, mutect2, varscan2
- BHLHE40 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99848304; called by muse, mutect2, varscan2
- BICC1 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV99570922; called by muse, mutect2, varscan2
- BICD2 | c.1738C>G p.R580G | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs573861187, COSV100794329, COSV63549224; called by muse, varscan2
- BMP10 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54897081; called by muse, mutect2, varscan2
- BMP5 | c.748T>A p.F250I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100896371; called by muse, mutect2, varscan2
- BMP5 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63705709; called by muse, mutect2, varscan2
- BNC1 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs908020925, COSV100597491; called by muse, mutect2, varscan2
- BNC1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597493; called by muse, mutect2, varscan2
- BNIP5 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs149597798; called by muse, mutect2, varscan2
- BPIFA3 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as rs1442950186, COSV100967129; called by muse, mutect2, varscan2
- BPIFC | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100301264; called by muse, mutect2, varscan2
- BPTF | c.9065C>T p.S3022L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100076069; called by muse, mutect2, varscan2
- BRCA2 | c.4641T>G p.D1547E | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.458); catalogued as COSV101204663; called by muse, mutect2, varscan2
- BRD8 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as rs1248177496, COSV99137680; called by muse, mutect2, varscan2
- BRDT | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100746594; called by muse, mutect2, varscan2
- BRDT | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1459355040, COSV100746595; called by muse, mutect2, varscan2
- BSN | c.6644T>A p.V2215D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99609884; called by muse, mutect2, varscan2
- C16orf90 | c.469C>T p.Q157* (on ENST00000399645 / NM_001353385.2; = p.Q148* on NM_001080524.2) | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs1374610011, COSV101290973; called by muse, mutect2, varscan2
- C1orf131 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100009722; called by muse, mutect2, varscan2
- C3 | c.655T>C p.S219P | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99837274; called by muse, mutect2, varscan2
- C4A | c.3178C>T p.R1060W | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779962386, COSV71177977; called by muse, mutect2, varscan2
- C6 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706697, COSV54710729; called by muse, mutect2, varscan2
- C7 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs753530114, COSV57477052; called by muse, mutect2, varscan2
- C7 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57470310, COSV57477578; called by muse, mutect2
- C8A | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100776666; called by muse, mutect2
- C8orf34 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1223592565, COSV100445763, COSV100447974; called by muse, mutect2, varscan2
- CACHD1 | c.1256T>G p.I419S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99263334; called by muse, mutect2, varscan2
- CACNA1A | c.5863G>A p.D1955N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100803257; called by muse, mutect2, varscan2
- CACNA1D | c.4976C>T p.S1659L (on ENST00000350061 / NM_001128840.3; = p.S1679L on NM_000720.4) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs766698651, COSV55441651, COSV55451678; called by muse, mutect2, varscan2
- CACNA1I | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361573; called by muse, mutect2, varscan2
- CACNA1S | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV62939052; called by muse, mutect2, varscan2
- CACNG3 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV99137165; called by muse, mutect2, varscan2
- CALCRL | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV66475296; called by muse, mutect2, varscan2
- CALN1 | c.278A>T p.D93V (on ENST00000329008 / NM_001017440.3; = p.D135V on NM_031468.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100209461, COSV61148062; called by muse, mutect2, varscan2
- CARMIL2 | c.3332G>A p.R1111Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1249078018, COSV99029526; called by muse, mutect2
- CASP10 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99629337; called by muse, mutect2, varscan2
- CATSPER2 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1379072948, COSV100390852, COSV100391001; called by muse, mutect2
- CATSPERB | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV99831797; called by muse, mutect2, varscan2
- CBX6 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs1278938760, COSV99328287; called by muse, mutect2, varscan2
- CC2D1A | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100528717; called by muse, mutect2, varscan2
- CCDC114 | c.1031A>C p.K344T | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100197116; called by muse, mutect2, varscan2
- CCDC141 | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99837499; called by muse, mutect2, varscan2
- CCDC148 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1296138417, COSV99321455; called by muse, mutect2, varscan2
- CCDC153 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.71); catalogued as COSV59541670; called by muse, mutect2, varscan2
- CCDC178 | c.1986G>A p.M662I (on ENST00000383096 / NM_001105528.3; = p.M624I on NM_198995.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs867565267, COSV55759521; called by muse, mutect2, varscan2
- CCDC178 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55766378; called by muse, mutect2, varscan2
- CCDC198 | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as rs146602887; called by muse, mutect2, varscan2
- CCDC70 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 77/107 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99665438; called by muse, mutect2, varscan2
- CCDC74B | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as COSV100134334; called by muse, mutect2, varscan2
- CCDC93 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60120572; called by muse, mutect2, varscan2
- CCNE1 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99388643; called by muse, mutect2, varscan2
- CCR8 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as rs1272224149, COSV100413194; called by muse, mutect2, varscan2
- CD1A | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs774994865, COSV56862255, COSV99192614; called by muse, mutect2, varscan2
- CD200R1L | c.795T>G p.N265K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV101236653; called by muse, mutect2, varscan2
- CD80 | c.257A>C p.E86A | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as COSV99958480; called by muse, mutect2, varscan2
- CD96 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51913310; called by muse, mutect2, varscan2
- CDH18 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.219); catalogued as rs866875588, COSV56959856; called by muse, mutect2, varscan2
- CDH20 | c.1629T>G p.F543L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99406577; called by muse, mutect2, varscan2
- CDH4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375893301; called by muse, mutect2, varscan2
- CDH6 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54063332; called by muse, varscan2
- CDH8 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.105); catalogued as rs867793640, COSV54905377; called by muse, mutect2, varscan2
- CEACAM4 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701173; called by muse, mutect2, varscan2
- CENPF | c.738T>G p.F246L | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100871994; called by muse, mutect2, varscan2
- CENPP | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100981423; called by muse, mutect2, varscan2
- CEP152 | c.2037G>T p.Q679H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV100359187; called by muse, mutect2, varscan2
- CETN1 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100511415; called by muse, mutect2, varscan2
- CFAP20DC | c.1556C>T p.S519L (on ENST00000482387 / NM_001351530.2; = p.S394L on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1369438708, COSV99919558; called by muse, mutect2, varscan2
- CFAP65 | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV58558317; called by muse, mutect2, varscan2
- CFAP69 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100290476; called by muse, mutect2, varscan2
- CFHR5 | c.254-1G>A p.X85_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as rs1229603831, COSV56819954; called by muse, mutect2, varscan2
- CFTR | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99139869; called by muse, mutect2, varscan2
- CHD6 | c.1691T>G p.L564R | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV100498721; called by muse, mutect2, varscan2
- CHERP | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV52222388, COSV99550530; called by muse, mutect2, varscan2
- CHIA | c.838G>A p.G280R (on ENST00000343320; = p.G172R on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1036117055, COSV100588848; called by muse, mutect2, varscan2
- CHIA | c.839G>A p.G280E (on ENST00000343320; = p.G172E on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs779244540, COSV58479708; called by muse, mutect2, varscan2
- CHL1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs1008914181, COSV56587285; called by muse, mutect2, varscan2
- CHP2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1332170564, COSV100270291; called by muse, mutect2, varscan2
- CHRM2 | c.541T>C p.F181L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100281963; called by muse, mutect2, varscan2
- CHRNB3 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51496741, COSV51497145; called by muse, mutect2, varscan2
- CHST15 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 58/88 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199887555, COSV60560141, COSV60560330; called by muse, mutect2, varscan2
- CINP | c.515A>T p.H172L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99392252; called by muse, mutect2, varscan2
- CKM | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as rs771688624, COSV99675424, COSV99675550; called by muse, varscan2
- CLCN1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58373130; called by muse, mutect2, varscan2
- CLDN14 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs964200327, COSV100579026; called by muse, mutect2, varscan2
- CLEC3A | c.277G>A p.G93S (on ENST00000651443; = p.G84S on NM_005752.6) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100222378; called by muse, mutect2, varscan2
- CLPX | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs1441228301, COSV100269662; called by muse, mutect2, varscan2
- CLSPN | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as rs1183812136, COSV99231548; called by muse, mutect2, varscan2
- CLSTN3 | c.1938T>G p.S646R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as COSV99867718; called by muse, mutect2, varscan2
- CLVS1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV57970800; called by muse, mutect2, varscan2
- CMYA5 | c.7391C>T p.S2464L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV101484392; called by muse, mutect2, varscan2
- CNOT11 | c.1117A>T p.N373Y | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99179387; called by muse, mutect2, varscan2
- CNTN2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as rs1558553460, COSV100085525, COSV59350728; called by muse, mutect2, varscan2
- CNTNAP2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.845); catalogued as rs956320440, COSV100674155, COSV62150880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.3034G>A p.G1012R | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100673081; called by muse, mutect2, varscan2
- COL13A1 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100637254, COSV100637837; called by muse, mutect2, varscan2
- COL22A1 | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 128/216 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1564189943, COSV100280846; called by muse, mutect2, varscan2
- COL22A1 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57334792; called by muse, mutect2, varscan2
- COL24A1 | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1169342449, COSV100994009; called by muse, mutect2, varscan2
- COL3A1 | c.4271G>A p.W1424* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV58592239; called by muse, mutect2, varscan2
- COL4A1 | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs867967840, COSV65424944; called by muse, mutect2
- COL4A4 | c.1806G>A p.G602= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as rs267599230; called by muse, varscan2
- COL4A5 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100089980; called by muse, mutect2, varscan2
- COL5A1 | c.3148G>A p.D1050N | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as COSV100880597; called by muse, mutect2, varscan2
- COMP | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1225587570, COSV99721588; called by muse, mutect2, varscan2
- COPA | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99616841; called by muse, mutect2, varscan2
- COX5A | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100466165; called by muse, mutect2, varscan2
- CPAMD8 | c.2795A>G p.N932S (on ENST00000651564; = p.N885S on NM_015692.5) | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV101488605; called by muse, mutect2, varscan2
- CPAMD8 | c.2104G>A p.E702K (on ENST00000651564; = p.E655K on NM_015692.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as rs1173529884, COSV52240736; called by muse, mutect2, varscan2
- CPAMD8 | c.628-1G>A p.X210_splice (on ENST00000651564; = p.X163_splice on NM_015692.5) | Splice Site (SNP) | VAF 30/83 reads (36%) | catalogued as COSV99359831; called by muse, mutect2, varscan2
- CPN2 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100103283; called by muse, mutect2, varscan2
- CPS1 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1233577562, COSV99244105; called by muse, mutect2, varscan2
- CPT1A | c.1252G>C p.V418L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as COSV55752702, COSV99681623; called by muse, mutect2, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2, varscan2
- CREBBP | c.589T>A p.L197I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.715); catalogued as COSV99272123; called by muse, varscan2
- CRHR2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100530170; called by muse, mutect2, varscan2
- CRIM1 | c.2282T>A p.F761Y | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV99754509; called by muse, mutect2, varscan2
- CRTC1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100119597; called by muse, mutect2, varscan2
- CSF2RA | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs200259335, COSV62625546; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2, varscan2
- CSMD2 | c.6601C>T p.P2201S | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV53889348; called by muse, mutect2, varscan2
- CSMD2 | c.4438G>A p.D1480N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99595547; called by muse, mutect2, varscan2
- CSMD2 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53904828, COSV99595555; called by muse, mutect2, varscan2
- CSMD3 | c.8327C>T p.S2776L (on ENST00000297405 / NM_001363185.1; = p.S2607L on NM_052900.3) | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.111); catalogued as rs751564616, COSV52160972, COSV52287189; called by muse, mutect2, varscan2
- CSMD3 | c.4349G>A p.G1450E (on ENST00000297405 / NM_001363185.1; = p.G1346E on NM_052900.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1255909158, COSV52235738; called by muse, mutect2, varscan2
- CSNK1E | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100725101, COSV63291034; called by muse, mutect2, varscan2
- CSNK1G1 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV100274473; called by muse, mutect2, varscan2
- CTNNA3 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375721994; called by muse, varscan2
- CTNND2 | c.2942T>A p.L981* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as COSV100481189; called by muse, mutect2, varscan2
- CTNND2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs1445784718, COSV58865546; called by muse, mutect2, varscan2
- CWF19L1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs372465564; called by muse, mutect2, varscan2
- CXCR1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as COSV99826434; called by muse, mutect2, varscan2
- CXCR4 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as rs1288565097, COSV99603200, COSV99603528; called by muse, mutect2, varscan2
- CXorf58 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101003106; called by muse, mutect2, varscan2
- CYBB | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101059827; called by muse, mutect2, varscan2
- CYLC2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as COSV100872535, COSV66336699; called by muse, mutect2, varscan2
- CYP2C9 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99583230; called by muse, mutect2, varscan2
- CYP2C9 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV99583234; called by muse, mutect2, varscan2
- CYP2F1 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs1268657511, COSV100463009; called by muse, mutect2, varscan2
- CYP3A4 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100315938; called by muse, mutect2, varscan2
- CYP4F12 | c.733T>A p.F245I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as COSV100216205; called by muse, mutect2, varscan2
- CYP4F22 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.431); catalogued as COSV99513190; called by muse, mutect2, varscan2
- CYP4F8 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1162821600, COSV100358252; called by muse, mutect2, varscan2
- CYP4X1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV100903370; called by muse, mutect2, varscan2
- CYP7B1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 71/116 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59592582, COSV59594156; called by muse, mutect2, varscan2
- CYTIP | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99938933; called by muse, mutect2, varscan2
- CYYR1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100177608; called by muse, mutect2, varscan2
- DAB1 | c.1738G>A p.D580N (on ENST00000371231; = p.D547N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV100976665; called by muse, mutect2, varscan2
- DBX1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1390959217, COSV99910322; called by muse, mutect2, varscan2
- DCAF4L1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV100296017, COSV60786553; called by muse, mutect2, varscan2
- DCAF6 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 26/47 reads (55%) | catalogued as rs1394103826, COSV100394879; called by muse, mutect2, varscan2
- DCC | c.4123C>T p.P1375S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV71431455, COSV71441327; called by muse, mutect2, varscan2
- DCST2 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99792265; called by muse, mutect2, varscan2
- DCSTAMP | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 144/197 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99886982; called by muse, mutect2, varscan2
- DCSTAMP | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.047); catalogued as COSV52579623; called by muse, mutect2, varscan2
- DDHD2 | c.1492A>G p.K498E | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101240809; called by muse, mutect2, varscan2
- DDR2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV63370752, COSV63372429; called by muse, mutect2, varscan2
- DDX27 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371321109; called by muse, mutect2, varscan2
- DEFB115 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs866556239, COSV68723000; called by muse, mutect2, varscan2
- DENR | c.527A>C p.D176A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99757424; called by muse, mutect2, varscan2
- DHRS2 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV99160502; called by muse, mutect2, varscan2
- DHRS4L2 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100632658; called by muse, mutect2, varscan2
- DKK3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV100485115; called by muse, mutect2
- DLG4 | c.1669G>T p.D557Y (on ENST00000399506 / NM_001321075.3; = p.D600Y on NM_001365.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs748458650, COSV100264011; called by muse, mutect2, varscan2
- DMBT1 | c.7372T>C p.Y2458H (on ENST00000338354 / NM_001377530.1; = p.Y1701H on NM_004406.3) | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100354129; called by muse, mutect2, varscan2
- DMRT3 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs778993459, COSV51902952; called by muse, mutect2, varscan2
- DNAH10 | c.12174G>A p.M4058I (on ENST00000409039; = p.M3997I on NM_207437.3) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs796742287, COSV101292353; called by muse, mutect2, varscan2
- DNAH17 | c.10525G>A p.G3509R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444638362, COSV101103510; called by muse, mutect2, varscan2
- DNAH17 | c.7597G>A p.G2533R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1243319748, COSV67758895; called by muse, mutect2, varscan2
- DNAH2 | c.7936C>T p.H2646Y | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209593; called by muse, mutect2, varscan2
- DNAH3 | c.9850G>A p.E3284K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV99770725; called by muse, mutect2, varscan2
- DNAH3 | c.9563A>G p.K3188R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs771487261, COSV99770728; called by muse, mutect2, varscan2
- DNAH5 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99454345; called by muse, mutect2, varscan2
- DNAH5 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV54212862; called by muse, mutect2, varscan2
- DNAH5 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99454355; called by muse, mutect2, varscan2
- DNAH7 | c.11753C>T p.P3918L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs1277796053, COSV100417637; called by muse, mutect2, varscan2
- DNAH7 | c.10354G>A p.G3452R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760943605, COSV56764012; called by muse, mutect2, varscan2
- DNAH7 | c.10307C>T p.P3436L | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417640; called by muse, mutect2, varscan2
- DNAH7 | c.9970C>T p.P3324S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.461); catalogued as COSV100417642; called by muse, mutect2, varscan2
- DNAH9 | c.6922C>T p.Q2308* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99308231; called by muse, mutect2, varscan2
- DNAH9 | c.12055C>T p.P4019S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306763, COSV99308233; called by muse, mutect2, varscan2
- DNAJC18 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV57416312; called by muse, mutect2, varscan2
- DOCK1 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99732796; called by muse, mutect2, varscan2
- DPP10 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1278855062, COSV59687953; called by muse, mutect2, varscan2
- DPY19L2 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100193046, COSV100194079; called by muse, mutect2, varscan2
- DPYD | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs267598786, COSV64609998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYS | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 168/446 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs751818026, COSV60907008; called by muse, varscan2
- DSC1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57145311; called by muse, mutect2, varscan2
- DSC2 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV51862645, COSV99199894; called by muse, mutect2, varscan2
- DSG1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs145081747, CM086709; called by muse, mutect2, varscan2
- DSG1 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57138627; called by muse, mutect2, varscan2
- DSG1 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57137053; called by muse, mutect2, varscan2
- DSG4 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs763798387, COSV100356432; called by muse, mutect2, varscan2
- DSG4 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs372042028; called by muse, mutect2, varscan2
- DST | c.22064C>T p.S7355F (on ENST00000361203 / NM_001374722.1; = p.S5065F on NM_015548.5) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99760134; called by muse, mutect2, varscan2
- DUOX2 | c.2971G>A p.G991R | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV66530837; called by muse, mutect2, varscan2
- DYRK4 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV99158156; called by muse, mutect2, varscan2
- DYRK4 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1178840162, COSV99158169; called by muse, mutect2, varscan2
- DYSF | c.2827G>A p.D943N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99250499; called by muse, mutect2, varscan2
- DZIP1L | c.1526G>A p.R509K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100551262, COSV100551740; called by muse, mutect2, varscan2
- EBF2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369154726; called by muse, mutect2, varscan2
- EEF2KMT | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs568457681, COSV99276021; called by muse, mutect2, varscan2
- EFTUD2 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101274560; called by muse, mutect2, varscan2
- EGFR | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV51785510, COSV51843325; called by muse, mutect2, varscan2
- EHMT2 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100977244; called by muse, mutect2, varscan2
- ELL2 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99427915; called by muse, mutect2, varscan2
- ELMO1 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 31/52 reads (60%) | catalogued as COSV60324128; called by muse, mutect2, varscan2
- ELMOD2 | c.575T>A p.L192H | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100063092; called by muse, mutect2, varscan2
- ELOVL4 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 27/50 reads (54%) | catalogued as COSV100876419; called by muse, mutect2, varscan2
- EMCN | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1280949297, COSV99598738; called by muse, mutect2, varscan2
- EMSY | c.3683C>T p.P1228L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100596085; called by muse, mutect2, varscan2
- ENPP3 | c.2041T>G p.F681V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV100718103; called by muse, mutect2, varscan2
- EPCAM | c.658-1G>A p.X220_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99764329; called by muse, varscan2
- EPCAM | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs752696226, COSV99764330; called by muse, varscan2
- EPHA7 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100992534, COSV65169780; called by muse, mutect2, varscan2
- EPHB6 | c.2669G>A p.G890E | Missense Mutation (SNP) | VAF 122/258 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV100844452, COSV63892659; called by muse, mutect2, varscan2
- EPHX2 | c.1277-2A>T p.X426_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100994831; called by muse, mutect2, varscan2
- EPO | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1384550253, COSV99402669; called by muse, mutect2, varscan2
- EPPK1 | c.4705G>A p.G1569R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554659993, COSV73261549; called by muse, mutect2
- EPS8 | c.2153T>A p.V718D | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV99843703; called by muse, mutect2, varscan2
- EPS8 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as rs1342230046, COSV99843706; called by muse, mutect2, varscan2
- EPX | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754901703, COSV99836781; called by muse, mutect2, varscan2
- ERBB4 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99628686; called by muse, mutect2, varscan2
- ERBB4 | c.1199-1G>A p.X400_splice | Splice Site (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99633313; called by muse, mutect2, varscan2
- ERBB4 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs748447524, COSV99627996, COSV99633316; called by muse, mutect2, varscan2
- ERC2 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1364328226, COSV99890224; called by muse, varscan2
- ERICH3 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as rs751252472, COSV58602685; called by muse, mutect2, varscan2
- ERICH3 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV58623166; called by muse, mutect2, varscan2
- ESD | c.683T>A p.F228Y | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV101099232; called by muse, mutect2
- EXOC6 | c.1308C>T p.F436= | Splice Region (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99592529; called by muse, mutect2, varscan2
- EYA1 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58172148; called by muse, mutect2
- EYA1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV100379378, COSV100380306; called by muse, mutect2, varscan2
- EYA4 | c.1463C>T p.A488V (on ENST00000531901 / NM_001301013.1; = p.A482V on NM_004100.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1042738234, COSV100766373; called by muse, mutect2, varscan2
- F5 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100889256; called by muse, mutect2, varscan2
- FABP9 | c.365A>T p.N122I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV100986957; called by muse, mutect2, varscan2
- FAM120C | c.1356G>C p.Q452H | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV100070478; called by muse, mutect2, varscan2
- FAM124A | c.179C>T p.P60L (on ENST00000322475 / NM_001242312.2; = p.P96L on NM_145019.4) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV99696463; called by muse, mutect2, varscan2
- FAM135B | c.3574G>A p.D1192N | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52717937; called by muse, mutect2, varscan2
- FAM135B | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV99427851; called by muse, mutect2, varscan2
- FAM135B | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99358228; called by muse, mutect2, varscan2
- FAM181A | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs764179723, COSV99967995; called by muse, mutect2
- FAM47A | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV60501014; called by muse, mutect2, varscan2
- FAM47B | c.1577A>G p.K526R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.591); catalogued as COSV100264649; called by muse, mutect2, varscan2
- FAM47C | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV63723407; called by muse, mutect2, varscan2
- FAM53C | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs757244107, COSV99524554; called by muse, mutect2, varscan2
- FANCM | c.4457T>C p.V1486A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99951668; called by muse, mutect2, varscan2
- FAT3 | c.5122G>A p.G1708R | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971244; called by muse, mutect2, varscan2
- FBN1 | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV100356448; called by muse, mutect2, varscan2
- FBXO38 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57026947; called by muse, mutect2, varscan2
- FBXO42 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100981941; called by muse, mutect2, varscan2
- FCRL4 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as rs764092875, COSV99620488; called by muse, mutect2, varscan2
- FER1L6 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs1201532168, COSV101206209; called by muse, mutect2
- FER1L6 | c.3701G>A p.G1234E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV67551932; called by muse, mutect2
- FER1L6 | c.4045C>T p.P1349S | Missense Mutation (SNP) | VAF 70/92 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV67548230; called by muse, mutect2, varscan2
- FER1L6 | c.5512C>T p.L1838F | Missense Mutation (SNP) | VAF 92/134 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV101206210; called by muse, varscan2
- FER1L6 | c.5549G>A p.S1850N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV67552456; called by muse, varscan2
- FFAR4 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 90/148 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65179161, COSV65179827; called by muse, mutect2, varscan2
- FGD2 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs761063246, COSV99236708; called by muse, mutect2, varscan2
- FGF5 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs201557946; called by muse, mutect2, varscan2
- FLG2 | c.4451G>A p.G1484E | Missense Mutation (SNP) | VAF 312/411 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV66169348; called by muse, mutect2, varscan2
- FLNC | c.4865C>T p.P1622L | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100368555; called by muse, mutect2, varscan2
- FLNC | c.6418C>T p.R2140W | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775518895, COSV100368765; called by muse, mutect2, varscan2
- FLT1 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56746227; called by muse, mutect2, varscan2
- FMN2 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1452483815, COSV60419486; called by muse, mutect2, varscan2
- FMN2 | c.3311G>A p.G1104E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); catalogued as COSV100147191; called by muse, mutect2
- FMN2 | c.4511G>A p.G1504E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60429267; called by muse, mutect2, varscan2
- FMN2 | c.4831G>A p.E1611K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV60448982; called by muse, mutect2, varscan2
- FMO1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.124); catalogued as rs577487000, COSV100707827, COSV100707957; called by muse, mutect2, varscan2
- FMOD | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs750548233, COSV100724636; called by muse, mutect2, varscan2
- FOXP2 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100647416; called by muse, mutect2, varscan2
- FPR2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV60673965; called by muse, mutect2, varscan2
- FREM1 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101083542; called by muse, mutect2, varscan2
- FRG2C | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.953); catalogued as rs1284646217; called by muse, mutect2, varscan2
- FRMPD2 | c.592A>T p.S198C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV100564211; called by muse, mutect2
- FRY | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100969939, COSV66572854, COSV66580479; called by muse, mutect2, varscan2
- FRYL | c.7037T>A p.V2346D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99978225; called by muse, mutect2, varscan2
- GABRE | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64818853; called by muse, mutect2, varscan2
- GABRE | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.95); PolyPhen benign (0.023); catalogued as rs866441978, COSV64819336; called by muse, mutect2, varscan2
- GAGE10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV101340058; called by muse, mutect2, varscan2
- GAL3ST1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV58892002; called by muse, mutect2, varscan2
- GALNT13 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV101224241; called by muse, mutect2, varscan2
- GALNTL6 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs146923140; called by muse, mutect2, varscan2
- GAN | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as COSV101634035; called by muse, mutect2, varscan2
- GAPT | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100576366; called by muse, mutect2, varscan2
- GAPT | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs1317913264, COSV100576368; called by muse, mutect2, varscan2
- GAREM1 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52514181; called by muse, mutect2, varscan2
- GAS2L1 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV99329726; called by muse, mutect2, varscan2
- GATA3 | c.1281C>G p.S427R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100651264; called by muse, mutect2, varscan2
- GBE1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780431086, COSV70097934; called by muse, mutect2, varscan2
- GBP2 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65069719; called by muse, mutect2, varscan2
- GCG | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as rs778526138, COSV100972858; called by muse, mutect2, varscan2
- GCLC | c.1118T>C p.V373A (on ENST00000643939; = p.V371A on NM_001498.4) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs750838576, COSV99988938; called by muse, mutect2, varscan2
- GDF10 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs1555207614; called by muse, mutect2, varscan2
- GFRAL | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV100475981; called by muse, mutect2, varscan2
- GGT5 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54068598; called by muse, mutect2, varscan2
- GHR | c.742T>A p.Y248N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV100052073; called by muse, mutect2, varscan2
- GIMAP4 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV99751158; called by muse, mutect2, varscan2
- GIMAP5 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV57530611; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2, varscan2
- GIMAP8 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs750008473, COSV56231017; called by muse, mutect2
- GJA8 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99569718; called by muse, mutect2, varscan2
- GJB6 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201783640, COSV99576169; called by muse, mutect2, varscan2
- GK2 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100726044; called by muse, mutect2, varscan2
- GLI2 | c.3118G>A p.E1040K (on ENST00000361492 / NM_001374353.1; = p.E1057K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1258559138, COSV100084365; called by muse, mutect2, varscan2
- GLIS1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV56551692; called by muse, mutect2, varscan2
- GLIS3 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.413); catalogued as COSV100174879; called by muse, mutect2, varscan2
- GLRA1 | c.698-2A>C p.X233_splice | Splice Site (SNP) | VAF 29/53 reads (55%) | catalogued as COSV99199691; called by muse, mutect2, varscan2
- GLRA3 | c.178A>T p.R60* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV56861960, COSV99928224; called by muse, mutect2, varscan2
- GLYAT | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1395774688, COSV53539994; called by muse, mutect2
- GOLGA4 | c.5937C>T p.I1979= | Splice Region (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100729181; called by muse, mutect2, varscan2
- GPA33 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1446633231, COSV63300588; called by muse, mutect2, varscan2
- GPR137C | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100397921; called by muse, mutect2, varscan2
- GPR32 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV99567392; called by muse, mutect2, varscan2
- GPR63 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as COSV100013578; called by muse, mutect2, varscan2
- GRIA3 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52059840; called by muse, mutect2, varscan2
- GRIA4 | c.189T>A p.N63K | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99234587; called by muse, mutect2, varscan2
- GRID2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV99937439; called by muse, mutect2, varscan2
- GRIN2A | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1245573153, COSV58022910; called by muse, mutect2, varscan2
- GRIN2B | c.2950C>T p.H984Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV74205803; called by muse, mutect2, varscan2
- GRK2 | c.381T>G p.S127R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as COSV100419760; called by muse, mutect2, varscan2
- GRXCR1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV67670324; called by muse, mutect2, varscan2
- GUCY1A2 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0.097); catalogued as COSV99976978; called by muse, mutect2, varscan2
- GUCY2F | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99485688; called by muse, mutect2, varscan2
- GYPB | c.221T>A p.I74N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1043433456, COSV51638699; called by muse, mutect2, varscan2
- GZMH | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs145534117, COSV99361894; called by muse, mutect2, varscan2
- GZMM | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1165398617, COSV52743364; called by muse, mutect2, varscan2
- H3-3B | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as rs867543814, COSV54667013; called by muse, mutect2, varscan2
- HAL | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99701668; called by muse, mutect2, varscan2
- HBG2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs63751148, CM0910355, COSV57964828; ClinVar: other; called by muse, mutect2, varscan2
- HCN3 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV64233522; called by muse, mutect2, varscan2
- HDAC11 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55473283; called by muse, mutect2
- HDAC9 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1258043089, COSV67766324; called by muse, varscan2
- HEATR5B | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV99250267; called by muse, mutect2, varscan2
- HECTD1 | c.2923A>T p.I975F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV101125728; called by muse, mutect2
- HECTD4 | c.6769C>T p.H2257Y | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101108385; called by muse, mutect2, varscan2
- HELLS | c.592T>G p.F198V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV99492418; called by muse, mutect2, varscan2
- HELLS | c.593T>C p.F198S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV99492423; called by muse, mutect2, varscan2
- HEPH | c.3013C>T p.H1005Y (on ENST00000343002; = p.H738Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100295768, COSV57960243; called by muse, varscan2
- HERC1 | c.14002C>T p.P4668S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV101496927; called by muse, mutect2, varscan2
- HGD | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as COSV99381440; called by muse, mutect2
- HGFAC | c.930G>T p.W310C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237787; called by muse, mutect2, varscan2
- HNRNPCL1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as rs757446413, COSV58613991; called by muse, mutect2, varscan2
- HNRNPL | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99670135, COSV99670600; called by muse, mutect2, varscan2
- HOXA1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs777453698, COSV58029430; called by muse, mutect2, varscan2
- HOXA3 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100415361; called by muse, mutect2, varscan2
- HRG | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV99215080; called by muse, mutect2, varscan2
- HS3ST4 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as COSV100503133; called by muse, mutect2, varscan2
- HS3ST6 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs770241158, COSV99562619, COSV99562884; called by muse, mutect2, varscan2
- HSD3B2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.515); catalogued as COSV101027569; called by muse, mutect2, varscan2
- HSD3B2 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.315); catalogued as COSV101027570; called by muse, mutect2, varscan2
- HTRA1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV64563874; called by muse, mutect2, varscan2
- HUS1B | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV100034247; called by muse, mutect2
- ICE1 | c.5737A>T p.K1913* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99665774; called by muse, mutect2
- ICE1 | c.6035T>C p.L2012S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99665776; called by muse, mutect2, varscan2
- IDO1 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398416927, COSV53716195, COSV53716700; called by muse, mutect2
- IDO2 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV58423750; called by muse, mutect2, varscan2
- IDO2 | c.584C>T p.P195L (on ENST00000389060; = p.P208L on NM_194294.2) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1481268548, COSV100584970; called by muse, mutect2, varscan2
- IFT172 | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV99563361; called by muse, mutect2, varscan2
- IGFN1 | c.2138G>A p.R713K (on ENST00000295591 / NM_001367841.1; = p.R3170K on NM_001164586.2) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV99813616; called by muse, mutect2, varscan2
- IGHJ5 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | PolyPhen probably damaging (0.986); catalogued as rs369944507; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs777480673; called by muse, mutect2, varscan2
- IGHV2-5 | c.288A>T p.K96N | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as rs782671794; called by muse, mutect2, varscan2
- IL13RA2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99683392; called by muse, mutect2, varscan2
- IL18RAP | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV99962425; called by muse, mutect2, varscan2
- IL1R1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs867221636, COSV52104935; called by muse, mutect2, varscan2
- INHBA | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1164410355, COSV99638421; called by muse, mutect2, varscan2
- INO80D | c.1863T>G p.F621L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV101305890; called by muse, mutect2, varscan2
- INTS5 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100399832; called by muse, mutect2
- INTS7 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs773236040, COSV65343758; called by muse, mutect2, varscan2
- IP6K3 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs147386946; called by muse, mutect2, varscan2
- IRF6 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65419166; called by muse, mutect2, varscan2
- IRGC | c.242A>T p.D81V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99746570; called by muse, mutect2
- ISLR2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1394661016, COSV62301583; called by muse, mutect2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- ITGAE | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs772832378, COSV53992503; called by muse, mutect2, varscan2
- ITGAL | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV63321908; called by muse, mutect2, varscan2
- ITGAM | c.2525G>A p.R842Q (on ENST00000648685 / NM_001145808.2; = p.R841Q on NM_000632.4) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs773006854, COSV54936404; called by muse, mutect2, varscan2
- ITGB4 | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99564788; called by muse, mutect2, varscan2
- ITGB6 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs540109604, COSV51790483; called by muse, mutect2, varscan2
- ITIH5 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs1305608579, COSV99905812; called by muse, varscan2
- ITPKB | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs777658082, COSV55267365; called by muse, mutect2, varscan2
- ITPR1 | c.1022G>A p.R341Q (on ENST00000354582; = p.R326Q on NM_002222.7) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs373174492; called by muse, mutect2, varscan2
- ITSN1 | c.4309C>T p.Q1437* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV101180998; called by muse, mutect2, varscan2
- ITSN2 | c.4841C>T p.P1614L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100744199; called by muse, mutect2, varscan2
- JADE3 | c.2080T>C p.F694L | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99510325; called by muse, mutect2, varscan2
- JAKMIP2 | c.1699A>T p.N567Y | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99509278; called by muse, mutect2, varscan2
- JHY | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.23); catalogued as COSV99912764, COSV99913810; called by muse, mutect2, varscan2
- KAT2A | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99863714; called by muse, mutect2, varscan2
- KAT6A | c.4049C>T p.S1350F | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99705919; called by muse, mutect2, varscan2
- KATNAL2 | c.289G>A p.A97T (on ENST00000356157 / NM_001353899.1; = p.A25T on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1325103328, COSV55298841, COSV99798179; called by muse, mutect2, varscan2
- KCNA1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV66839069; called by muse, mutect2, varscan2
- KCNA4 | c.1337T>A p.I446N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100069286; called by muse, mutect2, varscan2
- KCNAB3 | c.1169T>C p.M390T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100376154; called by muse, mutect2, varscan2
- KCNB1 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.346); catalogued as COSV100870595; called by muse, mutect2, varscan2
- KCNB2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 11/189 reads (6%) | catalogued as COSV101579002; called by muse, mutect2
- KCNH5 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100528211; called by muse, mutect2, varscan2
- KCNH5 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV59781064; called by muse, mutect2, varscan2
- KCNH6 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV100121271; called by muse, mutect2, varscan2
- KCNH7 | c.3113T>G p.L1038R | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100149884; called by muse, mutect2, varscan2
- KCNH7 | c.2795G>A p.S932N | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs771283553, COSV100149886; called by muse, mutect2, varscan2
- KCNJ1 | c.395T>A p.F132Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV100131488; called by muse, mutect2, varscan2
- KCNJ16 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52250893; called by muse, mutect2, varscan2
- KCNJ2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as rs1443012108, COSV99696542; called by muse, mutect2, varscan2
- KCNK10 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1388738317, COSV100068090; called by muse, mutect2, varscan2
- KCNK3 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.037); catalogued as rs527873552, COSV100257218; called by muse, varscan2
- KCNK5 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs775162928, COSV63988500; called by muse, mutect2, varscan2
- KCNQ3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101196456, COSV66468814; called by muse, mutect2, varscan2
- KCNT1 | c.2614G>A p.A872T (on ENST00000488444; = p.A891T on NM_020822.3) | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs752835491, COSV99706723; called by muse, mutect2, varscan2
- KCNU1 | c.2431A>T p.T811S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.024); catalogued as COSV101299433; called by muse, mutect2, varscan2
- KCNV2 | c.1336del p.H446Tfs*8 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs1563796333, COSV66056804; called by mutect2, pindel, varscan2
- KCTD16 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101568899, COSV72580047; called by muse, mutect2, varscan2
- KEL | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as COSV100787307; called by muse, mutect2, varscan2
- KHDRBS2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1324524333, COSV55477288; called by muse, varscan2
- KHNYN | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748173478, COSV52160731, COSV99250127; called by muse, mutect2, varscan2
- KIAA1217 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100287332; called by muse, varscan2
- KIAA1549L | c.3869C>T p.P1290L (on ENST00000321505; = p.P1587L on NM_012194.3) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV99684495; called by muse, mutect2, varscan2
- KIF2B | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs1387686347, COSV52129963; called by muse, mutect2
- KIF2C | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs759800312, COSV100945879; called by muse, mutect2, varscan2
- KIF3C | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53097426, COSV99267967; called by muse, mutect2, varscan2
- KIF7 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs543188623, COSV101067974; called by muse, mutect2, varscan2
- KLHDC7A | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV101272854; called by muse, mutect2
- KLHL1 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV64769952, COSV64775148; called by muse, mutect2, varscan2
- KLHL1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.194); catalogued as rs754998896, COSV64781118; called by muse, mutect2, varscan2
- KLHL3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV100553580; called by muse, mutect2, varscan2
- KMT2C | c.14560A>G p.N4854D | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100076622; called by muse, mutect2, varscan2
- KNG1 | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99405871; called by muse, mutect2, varscan2
- KPRP | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as COSV100908805; called by muse, mutect2, varscan2
- KRT26 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs756147194, COSV100156639, COSV59415340; called by muse, mutect2, varscan2
- KRT33B | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99290858; called by muse, mutect2
- KRT34 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101222726; called by muse, mutect2, varscan2
- KRT7 | c.598-1G>A p.X200_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | catalogued as COSV59330370; called by muse, varscan2
- KRT7 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1565718344, COSV100081817; called by muse, varscan2
- KRT77 | c.1236T>G p.D412E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.456); catalogued as rs778177726, COSV100527280; called by muse, mutect2, varscan2
- KRT86 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs752211932, COSV53291952; called by muse, mutect2, varscan2
- KRTAP9-4 | c.454T>A p.F152I | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100484969; called by muse, mutect2, varscan2
- L3MBTL4 | c.469A>T p.K157* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99531243; called by muse, mutect2, varscan2
- LAMB4 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306122682, COSV52718186; called by muse, mutect2, varscan2
- LAMP3 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as rs749838133, COSV99660779; called by muse, mutect2, varscan2
- LARP4B | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1447822598, COSV100295695; called by muse, mutect2, varscan2
- LCN2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99478354; called by muse, mutect2, varscan2
- LCT | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300072757, COSV99930491; called by muse, mutect2, varscan2
- LDHD | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747908313, COSV55581544; called by muse, mutect2, varscan2
- LDLRAD3 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV100215273; called by muse, mutect2, varscan2
- LELP1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs761668608, COSV64202571; called by muse, mutect2, varscan2
- LHX2 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV101010093; called by muse, mutect2, varscan2
- LIFR | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665555; called by muse, mutect2, varscan2
- LILRB5 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV100300825; called by muse, mutect2, varscan2
- LILRB5 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV100300828; called by muse, mutect2, varscan2
- LIMCH1 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV58297374; called by muse, mutect2, varscan2
- LITAF | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs774532093, COSV100243243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMAN1L | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV59003758; called by muse, mutect2, varscan2
- LNP1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758984362, COSV67347020; called by muse, mutect2, varscan2
- LONRF2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV66541007; called by muse, mutect2, varscan2
- LRBA | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766332412, COSV63952342; called by muse, mutect2, varscan2
- LRFN2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs959343309, COSV57823890; called by muse, mutect2, varscan2
- LRGUK | c.2099G>A p.S700N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs754102857, COSV99604709; called by muse, varscan2
- LRIG1 | c.1181T>C p.I394T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99834446; called by muse, mutect2, varscan2
- LRIT3 | c.958T>G p.S320A | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1286867240, COSV100016432; called by muse, mutect2, varscan2
- LRP1 | c.7526G>A p.R2509Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs764820554, COSV54523495; called by muse, mutect2, varscan2
- LRP2 | c.12193C>T p.R4065* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as rs1228784624, COSV55545838; called by muse, mutect2, varscan2
- LRP2 | c.10792G>A p.E3598K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs866160148, COSV55553670; ClinVar: uncertain significance; called by muse, varscan2
- LRP2 | c.3892G>A p.D1298N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790313; called by muse, mutect2, varscan2
- LRP8 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100036931; called by muse, mutect2, varscan2
- LRRC28 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs1211573594, COSV57343297; called by muse, mutect2, varscan2
- LRRIQ3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs765391855, COSV63041539; called by muse, mutect2, varscan2
- LTBP2 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.871); catalogued as COSV56209308; called by muse, mutect2, varscan2
- MACC1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV100256301; called by muse, mutect2, varscan2
- MAGEA10 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT tolerated (0.37); PolyPhen benign (0.275); catalogued as COSV99726930; called by muse, mutect2, varscan2
- MAGEA12 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1556833391, COSV100757077; called by muse, mutect2, varscan2
- MAGEA4 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 95/141 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99367725; called by muse, mutect2, varscan2
- MAGEB3 | c.593T>G p.F198C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100854821; called by muse, mutect2, varscan2
- MAGEC1 | c.2984C>T p.S995F | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99596607; called by muse, mutect2, varscan2
- MAGEC2 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs772829264, COSV99909946, COSV99909951; called by muse, mutect2, varscan2
- MAGEC2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV55997889; called by muse, mutect2, varscan2
- MAGI3 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs923647476, COSV100290465; called by muse, mutect2, varscan2
- MAN2A2 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs773489112, COSV64638829; called by muse, mutect2, varscan2
- MAP1A | c.2771G>A p.R924K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778597124, COSV100289255; called by muse, mutect2, varscan2
- MAP1A | c.7795G>A p.E2599K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); catalogued as rs867064587, COSV55809291; called by muse, mutect2, varscan2
- MAP3K11 | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100482762; called by muse, varscan2
- MAP3K21 | c.2899C>T p.Q967* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs761367644, COSV64041578; called by muse, mutect2, varscan2
- MAP7D1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100294824; called by muse, mutect2, varscan2
- MAST4 | c.1099C>T p.H367Y (on ENST00000403625 / NM_001164664.2; = p.H178Y on NM_015183.3) | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99845908; called by muse, mutect2, varscan2
- MBTD1 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100899346; called by muse, mutect2, varscan2
- MC5R | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100229171; called by muse, mutect2, varscan2
- MCTP1 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.188); catalogued as COSV100388215; called by muse, mutect2, varscan2
- MCTP1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100388217; called by muse, mutect2, varscan2
- MCTP2 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV63296888, COSV63297588; called by muse, mutect2, varscan2
- MDN1 | c.11241A>T p.E3747D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV101021844; called by muse, mutect2, varscan2
- MDN1 | c.8092G>T p.V2698F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101021845; called by muse, mutect2, varscan2
- MED13 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 51/91 reads (56%) | catalogued as COSV101181413; called by muse, mutect2, varscan2
- MED23 | c.2888T>G p.F963C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645410; called by muse, mutect2, varscan2
- MESP2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs1164656326, COSV100510864; called by muse, mutect2, varscan2
- METAP2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99704988; called by muse, mutect2, varscan2
- MGAM | c.2983T>A p.F995I | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV101527759; called by muse, mutect2, varscan2
- MGAM | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs749121609, COSV72073544; called by muse, mutect2, varscan2
- MGAM | c.5405G>A p.W1802* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV72075119; called by muse, mutect2, varscan2
- MGAM | c.5406G>A p.W1802* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs760283646, COSV101527609, COSV101527761; called by muse, mutect2, varscan2
- MGAT4C | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.943); catalogued as COSV59833249, COSV59835085; called by muse, mutect2, varscan2
- MIA2 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as COSV99696939; called by muse, mutect2, varscan2
- MIA3 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.551); catalogued as COSV100719537; called by muse, mutect2, varscan2
- MICAL2 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99818024, COSV99818394; called by muse, mutect2, varscan2
- MIGA1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV100889753, COSV100889816; called by muse, mutect2, varscan2
- MKI67 | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 112/165 reads (68%) | SIFT tolerated (0.53); PolyPhen benign (0.285); catalogued as rs754733861, COSV64077954; called by muse, mutect2, varscan2
- MKRN1 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV55436248, COSV99751902; called by muse, mutect2, varscan2
- MMP17 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62179444; called by muse, mutect2, varscan2
- MMP26 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs368459718, COSV56173504; called by muse, mutect2, varscan2
- MOB3A | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1321593466, COSV100830080; called by muse, mutect2, varscan2
- MORC3 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV101247764; called by muse, mutect2, varscan2
- MORN3 | c.136G>C p.V46L | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100804513; called by muse, mutect2, varscan2
- MPL | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV100991787; called by muse, mutect2, varscan2
- MROH2B | c.4307C>T p.S1436L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs867528082, COSV68182690; called by muse, mutect2, varscan2
- MROH2B | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68181244; called by muse, mutect2, varscan2
- MROH5 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV101436144; called by muse, mutect2
- MS4A4A | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.285); catalogued as COSV100557935; called by muse, mutect2, varscan2
- MTF1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65962654; called by muse, mutect2, varscan2
- MTO1 | c.821T>A p.I274N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100940569; called by muse, mutect2, varscan2
- MTUS2 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV99686640; called by muse, mutect2
- MUC16 | c.41603C>T p.P13868L | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.995); catalogued as rs1227313894, COSV101110094; called by muse, mutect2, varscan2
- MUC16 | c.39772G>A p.E13258K | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV101110095; called by muse, mutect2, varscan2
- MUC16 | c.35587C>T p.P11863S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.047); catalogued as COSV67488943; called by muse, mutect2, varscan2
- MUC16 | c.16898C>T p.S5633F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1446280776, COSV67445101; called by muse, mutect2, varscan2
- MUC16 | c.15482G>A p.G5161E | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as rs868805628, COSV67487225; called by muse, mutect2, varscan2
- MUC16 | c.12460G>A p.E4154K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV101201769; called by muse, mutect2, varscan2
- MUC17 | c.5071C>T p.P1691S | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60303323; called by muse, mutect2, varscan2
- MUC17 | c.10175C>T p.S3392L | Missense Mutation (SNP) | VAF 181/441 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs776923178, COSV100075099; called by muse, mutect2, varscan2
- MUC17 | c.12269C>T p.T4090I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs781438723, COSV100075101; called by muse, mutect2, varscan2
- MXRA5 | c.6811C>T p.P2271S | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99479358; called by muse, mutect2, varscan2
- MYBL2 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99406758; called by muse, mutect2, varscan2
- MYH1 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99876925; called by muse, mutect2, varscan2
- MYH15 | c.1898T>G p.F633C | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99844340; called by muse, mutect2, varscan2
- MYH4 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs199943889, COSV55113030; called by muse, mutect2, varscan2
- MYH4 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55115570, COSV55120002; called by muse, mutect2, varscan2
- MYO18B | c.7217T>C p.F2406S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100125250; called by muse, mutect2, varscan2
- MYO1A | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100271274; called by muse, mutect2, varscan2
- MYO5B | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53228462; called by muse, varscan2
- MYO5C | c.3935G>A p.R1312Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs770508177, COSV55902363; called by muse, mutect2, varscan2
- MYO6 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1303908885, COSV64118608; called by muse, mutect2, varscan2
- N4BP2 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV54704774; called by muse, mutect2, varscan2
- NACA2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs752237901, COSV101478527; called by muse, mutect2, varscan2
- NALCN | c.4751G>A p.R1584K | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.194); catalogued as rs775579391, COSV99217839; called by muse, mutect2, varscan2
- NAV1 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99819717; called by muse, mutect2, varscan2
- NBPF11 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.857); catalogued as rs1200961673; called by muse, mutect2, varscan2
- NCKAP5 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.051); catalogued as COSV100494472; called by muse, mutect2, varscan2
- NCOA1 | c.951G>A p.V317= | Splice Region (SNP) | VAF 43/64 reads (67%) | catalogued as COSV99947106; called by muse, mutect2, varscan2
- NDN | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1566793269, COSV59358849; called by muse, varscan2
- NDOR1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1207468064, COSV100641648; called by muse, mutect2, varscan2
- NDOR1 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201387675, COSV100789093; called by muse, mutect2, varscan2
- NDUFS7 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs1052564692, CM165967, COSV52041035; called by muse, mutect2, varscan2
- NEBL | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs901962676, COSV101009363; called by muse, mutect2, varscan2
- NEBL | c.947A>G p.H316R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101009365; called by muse, mutect2, varscan2
- NEFM | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55334054, COSV99647584; called by muse, mutect2, varscan2
- NEFM | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as rs865855175, COSV55333250; called by muse, mutect2, varscan2
- NEIL2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV99462503; called by muse, mutect2, varscan2
- NEUROD4 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 184/391 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.854); catalogued as COSV99670174; called by muse, mutect2, varscan2
- NEXMIF | c.3053G>A p.G1018D | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV50049607; called by muse, mutect2, varscan2
- NFASC | c.230G>A p.R77Q (on ENST00000339876 / NM_001378329.1; = p.R71Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757003214, COSV58365309; called by muse, mutect2, varscan2
- NFATC4 | c.2477T>A p.F826Y | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99151169; called by muse, mutect2, varscan2
- NFX1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV100582466; called by muse, mutect2, varscan2
- NFX1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100582468, COSV59309063; called by muse, mutect2, varscan2
- NINL | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54004829, COSV99626352; called by muse, mutect2, varscan2
- NISCH | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100402261; called by muse, mutect2, varscan2
- NKAIN3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs765524369, COSV60654926; called by muse, mutect2, varscan2
- NLRC4 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as COSV100707519; called by muse, mutect2, varscan2
- NLRC5 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV99348286; called by muse, mutect2, varscan2
- NLRP1 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335507; called by muse, mutect2, varscan2
- NLRP5 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs373401163; called by muse, mutect2, varscan2
- NME8 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs144650767; called by muse, mutect2, varscan2
- NME8 | c.1429G>A p.G477R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV52249032; called by muse, mutect2, varscan2
- NOM1 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV99316078; called by muse, mutect2, varscan2
- NOS1 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57607333; called by muse, mutect2, varscan2
- NOS2 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs1452540488, COSV100569879, COSV100569898; called by muse, mutect2, varscan2
- NOTCH2 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV56701584, COSV99866846; called by muse, mutect2, varscan2
- NOTCH2 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs587640013, COSV99866849; called by muse, mutect2, varscan2
- NOTCH4 | c.3984G>T p.W1328C | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as COSV100901070; called by muse, mutect2, varscan2
- NOTCH4 | c.3983G>A p.W1328* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100901072; called by muse, mutect2
- NOVA1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV99948788; called by muse, mutect2, varscan2
- NOVA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | catalogued as COSV57472701, COSV57490260; called by muse, mutect2, varscan2
- NPAP1 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as COSV61511507; called by muse, mutect2, varscan2
- NPAS4 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.809); catalogued as COSV100215274; called by muse, mutect2, varscan2
- NPR1 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100902082; called by muse, mutect2, varscan2
- NPSR1 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100707192, COSV62202393; called by muse, mutect2, varscan2
- NPY | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386633782, COSV99635619; called by muse, mutect2, varscan2
- NRAP | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100748619; called by muse, mutect2
- NRP1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 102/184 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); catalogued as COSV99589635; called by muse, mutect2, varscan2
- NRXN2 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99635872; called by muse, mutect2, varscan2
- NSUN7 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as rs767790645, COSV100349519, COSV100349735; called by muse, mutect2, varscan2
- NTSR1 | c.918T>G p.R306= | Splice Region (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100980719; called by muse, mutect2, varscan2
- NUP42 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs1291768096, COSV99331179; called by muse, mutect2, varscan2
- NXF3 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 105/152 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV101222084; called by muse, mutect2, varscan2
- OBI1 | c.297T>G p.Y99* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99932629; called by muse, mutect2
- OGT | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV101035644; called by muse, mutect2, varscan2
- OLA1 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225019836, COSV52971335, COSV99506861; called by muse, mutect2, varscan2
- OLA1 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99506864; called by muse, mutect2, varscan2
- OLFML3 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57436990; called by muse, mutect2, varscan2
- OPTC | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs375920047; called by muse, mutect2, varscan2
- OR10H1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100612507; called by muse, mutect2, varscan2
- OR10H2 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100008894; called by muse, mutect2, varscan2
- OR10H5 | c.304T>C p.F102L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV100454810; called by muse, mutect2, varscan2
- OR10J3 | c.839C>G p.T280S | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100171891; called by muse, mutect2, varscan2
- OR10W1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV67720858; called by muse, mutect2, varscan2
- OR14C36 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV58602821; called by muse, mutect2, varscan2
- OR14J1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV101012867; called by muse, mutect2, varscan2
- OR2A14 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1187715234, COSV68717939; called by muse, mutect2, varscan2
- OR2F1 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 123/294 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV101231335; called by muse, mutect2, varscan2
- OR2F1 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs776312015, COSV67330731; called by muse, mutect2, varscan2
- OR2L2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs185106511, COSV63548141; called by muse, mutect2, varscan2
- OR2M3 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101513523, COSV71759188; called by muse, mutect2, varscan2
- OR2T12 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV58775952; called by muse, mutect2, varscan2
- OR2T2 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100737805, COSV61618009; called by muse, mutect2, varscan2
- OR2T33 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775475303, COSV58813890; called by muse, mutect2, varscan2
- OR2T8 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV60665038; called by muse, mutect2, varscan2
- OR4C13 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.141); catalogued as COSV101634244; called by muse, mutect2, varscan2
- OR4D11 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs267603040, COSV100506640, COSV57585961; called by muse, mutect2, varscan2
- OR4E2 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1472193881, COSV57732519; called by muse, mutect2, varscan2
- OR4F15 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); catalogued as COSV100173957; called by muse, mutect2, varscan2
- OR4K1 | c.258T>G p.F86L | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53458639, COSV99579416; called by muse, mutect2, varscan2
- OR4K14 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs143492862, COSV100520397, COSV59293010; called by muse, mutect2, varscan2
- OR4N2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60050301; called by muse, mutect2, varscan2
- OR4S1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs866149383, COSV60679676, COSV60679764; called by muse, mutect2, varscan2
- OR51B5 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100332410, COSV100332686; called by muse, mutect2, varscan2
- OR51F1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV58579382, COSV58580890; called by muse, mutect2
- OR51F2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs767787431, COSV59063793; called by muse, mutect2, varscan2
- OR51I1 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100972063, COSV66509410; called by muse, mutect2, varscan2
- OR51I2 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV100413479; called by muse, mutect2, varscan2
- OR51L1 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100386495; called by muse, mutect2, varscan2
- OR51T1 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100434498, COSV59026263; called by muse, mutect2, varscan2
- OR52B6 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61447187; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- OR52N4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV57890290; called by muse, mutect2, varscan2
- OR52N5 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57698920; called by muse, mutect2, varscan2
- OR56B1 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as rs1204318800, COSV100402740; called by muse, mutect2, varscan2
- OR5B2 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV100222990; called by muse, mutect2, varscan2
- OR5B3 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as rs866672705, COSV58679249; called by muse, mutect2, varscan2
- OR5H15 | c.197T>C p.L66S | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100736771; called by muse, mutect2, varscan2
- OR5H6 | c.198G>A p.W66* (on ENST00000642105; = p.W50* on NM_001005479.2) | Nonsense Mutation (SNP) | VAF 106/237 reads (45%) | catalogued as rs1559838807, COSV101051819; called by muse, mutect2, varscan2
- OR5V1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV65828046; called by muse, mutect2, varscan2
- OR6C65 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs757704562, COSV101110210, COSV65568726; called by muse, mutect2, varscan2
- OR6C76 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100094342, COSV60388905; called by muse, mutect2, varscan2
- OR6K6 | c.284C>T p.S95F (on ENST00000368144; = p.S71F on NM_001005184.1) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63743789; called by muse, mutect2, varscan2
- OR6K6 | c.989G>A p.R330K (on ENST00000368144; = p.R306K on NM_001005184.1) | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933799; called by muse, mutect2, varscan2
- OR8B3 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs530631592, COSV63541472; called by muse, mutect2
1,080 further variants in this file (433 protein-altering or splice-affecting, 594 silent, 53 other) are not listed here.
